Somatic mutation profile of tumor specimen C3N-03664-01 (aliquot CPT0196210009) from CPTAC case C3N-03664, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 58.5 years (21,361 days).
Specimen C3N-03664-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45feacbf-ebbc-4ff7-b651-c11ab3dbb882.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03664-71 (Blood Derived Normal), aliquot CPT0196330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3fcb884d-1e78-4d6e-b553-7ba5fd029433

The open-access MAF lists 199 somatic variants for this specimen: 134 protein-altering or splice-affecting, 47 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 47, Frame Shift Del 9, Nonsense Mutation 7, Intron 6, 3'UTR 6, Splice Site 3, RNA 2, 5'UTR 2, Frame Shift Ins 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.2680G>T p.D894Y | Missense Mutation (SNP) | VAF 43/87 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59214349, COSV59219610; called by muse, mutect2, varscan2
- TP53 | c.636del p.R213Dfs*34 | Frame Shift Del (DEL) | VAF 287/562 reads (51%) | catalogued as rs864309495, CD011205, COSV52729299; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA4 | c.2350G>A p.D784N | Missense Mutation (SNP) | VAF 105/510 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV100933065; called by muse, mutect2, varscan2
- AC097636.1 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs764711838, COSV101469663, COSV101469670, COSV71309616; called by muse, mutect2, varscan2
- ADAM23 | c.1802A>G p.N601S | Missense Mutation (SNP) | VAF 143/373 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as rs757037417; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1450G>C p.E484Q | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV52819781; called by muse, mutect2, varscan2
- C3orf85 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.439); catalogued as rs113450306; called by muse, varscan2
- CALN1 | c.124C>T p.R42* (on ENST00000329008 / NM_001017440.3; = p.R84* on NM_031468.4) | Nonsense Mutation (SNP) | VAF 75/218 reads (34%) | catalogued as rs1267060461, COSV61133555; called by muse, mutect2, varscan2
- CDH5 | c.2008G>A p.G670R | Missense Mutation (SNP) | VAF 98/467 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as rs748328195; called by muse, mutect2, varscan2
- CRISP1 | c.741G>C p.E247D | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as COSV100236734; called by muse, mutect2, varscan2
- CSGALNACT2 | c.809C>G p.S270* | Nonsense Mutation (SNP) | VAF 28/154 reads (18%) | catalogued as COSV65676289; called by muse, mutect2, varscan2
- CTLA4 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 159/467 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as CM1412308, COSV55592701; called by muse, mutect2, varscan2
- CYLC1 | c.1266A>T p.E422D | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV61410169; called by muse, mutect2, varscan2
- DCHS1 | c.8666G>A p.R2889Q | Missense Mutation (SNP) | VAF 68/278 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as rs372734296; called by muse, mutect2, varscan2
- DENND2C | c.1765G>A p.E589K (on ENST00000393274 / NM_001256404.2; = p.E532K on NM_198459.4) | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs142134642; called by muse, mutect2, varscan2
- DMGDH | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs751964939, COSV54866309; called by muse, mutect2, varscan2
- DNAH12 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61067001; called by muse, mutect2, varscan2
- EAF1 | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV67541861; called by muse, mutect2, varscan2
- FAM135B | c.3213G>T p.L1071F | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV52725040; called by muse, mutect2, varscan2
- FAM47B | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 100/198 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs200459858, COSV61453520, COSV61453824; called by muse, mutect2, varscan2
- FMNL1 | c.2804G>A p.R935Q | Missense Mutation (SNP) | VAF 62/402 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.258); catalogued as rs1351822937; called by muse, mutect2, varscan2
- GABRR3 | c.1111A>G p.R371G | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs745779200; called by muse, mutect2, varscan2
- GALC | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs926735313; called by muse, mutect2, varscan2
- GTF3C1 | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 23/136 reads (17%) | catalogued as rs1333734389, COSV62240042; called by muse, mutect2, varscan2
- HIVEP1 | c.2318C>T p.S773L | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65101081; called by muse, mutect2, varscan2
- IDH3G | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs1333506813; called by muse, mutect2, varscan2
- INPP5D | c.3043G>A p.E1015K (on ENST00000445964 / NM_001017915.3; = p.E1014K on NM_005541.5) | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765981948; called by muse, mutect2, varscan2
- ITGAM | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs188605180, COSV54938526; called by muse, mutect2, varscan2
- KREMEN2 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 62/279 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99566980; called by muse, mutect2
- MAP4K1 | c.323C>G p.S108C | Missense Mutation (SNP) | VAF 82/401 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs774924542, COSV50263741, COSV50264542; called by muse, mutect2, varscan2
- MTERF3 | c.1189A>G p.I397V | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771977698; called by muse, mutect2, varscan2
- NECAB2 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs1424718853; called by muse, mutect2, varscan2
- NOTCH1 | c.3134G>T p.C1045F | Missense Mutation (SNP) | VAF 118/272 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53073894; called by muse, mutect2, varscan2
- NSD1 | c.4337C>G p.T1446S | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs762327687; called by muse, mutect2, varscan2
- OR5B3 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV58676824; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.425C>T p.A142V (on ENST00000259318 / NM_001136562.3; = p.A373V on NM_007203.5) | Missense Mutation (SNP) | VAF 94/213 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs143371794; called by muse, mutect2, varscan2
- PDE3B | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99962595; called by muse, mutect2, varscan2
- PEG3 | c.4066G>A p.E1356K | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV55632976; called by muse, mutect2, varscan2
- POTEM | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 169/1019 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.511); catalogued as COSV69156657; called by muse, mutect2, varscan2
- RAB41 | c.275G>A p.R92H (on ENST00000374473 / NM_001363807.1; = p.R91H on NM_001032726.3) | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1339622797; called by muse, mutect2, varscan2
- SDF2L1 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 156/540 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1161270954; called by muse, mutect2, varscan2
- SMCR8 | c.1582C>T p.L528F | Missense Mutation (SNP) | VAF 193/611 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs748600621; called by muse, mutect2, varscan2
- SPART | c.815G>T p.C272F | Missense Mutation (SNP) | VAF 39/256 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62084908; called by muse, mutect2, varscan2
- SRR | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV56785348; called by muse, mutect2, varscan2
- TMPRSS6 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 90/537 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs188371820, COSV60982929; called by muse, mutect2, varscan2
- TNFRSF10B | c.589A>T p.T197S | Missense Mutation (SNP) | VAF 95/354 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.444); catalogued as rs777040114; called by muse, mutect2, varscan2
- TP53INP2 | c.226C>A p.P76T | Missense Mutation (SNP) | VAF 72/271 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344847948; called by muse, mutect2, varscan2
- WDFY3 | c.8929C>T p.R2977* | Nonsense Mutation (SNP) | VAF 38/208 reads (18%) | catalogued as rs1406414804; called by muse, mutect2, varscan2
- WNT9A | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 55/317 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.107); catalogued as COSV55293234; called by muse, mutect2, varscan2
- XRN1 | c.2084A>T p.D695V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs749127897; called by muse, varscan2
- ZFHX4 | c.9155C>T p.P3052L | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV51462183; called by muse, mutect2, varscan2
- ZNF502 | c.540G>C p.E180D | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as rs759185162; called by muse, mutect2, varscan2
- ZNF518B | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs202108142; called by muse, mutect2, varscan2
- ZNF99 | c.1600A>C p.K534Q | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as rs375631046, COSV68057197; called by muse, mutect2, varscan2
- ABCA9 | c.3037G>A p.E1013K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.102); called by muse, varscan2
- ACADL | c.1199+2T>G p.X400_splice | Splice Site (SNP) | VAF 42/227 reads (19%) | called by muse, mutect2, varscan2
- ACE | c.1370T>C p.M457T | Missense Mutation (SNP) | VAF 84/463 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- ACP7 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 128/316 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- AKAP10 | c.1896A>C p.E632D | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ANKRD9 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 63/280 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ARHGAP39 | c.2356_2372delinsTTTTTTAAGGGTACGGC p.I786_Q791delinsFFKGTA | Missense Mutation (ONP) | VAF 11/137 reads (8%) | called by mutect2*, pindel
- ATF7 | c.1103_1113del p.V368Gfs*16 (on ENST00000548446 / NM_001366555.2; = p.V357Gfs*16 on NM_006856.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 58/620 reads (9%) | called by mutect2, pindel
- BBS7 | c.1268A>G p.N423S | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- CA2 | c.118T>A p.Y40N | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CCNF | c.1732C>G p.L578V | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- CDR1 | c.413G>T p.R138I | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- CELF4 | c.551_560del p.L184Pfs*11 | Frame Shift Del (DEL) | VAF 33/217 reads (15%) | called by mutect2, pindel, varscan2
- CNOT7 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 41/199 reads (21%) | called by muse, mutect2, varscan2
- CNTN4 | c.1055dup p.N352Kfs*10 | Frame Shift Ins (INS) | VAF 29/166 reads (17%) | called by mutect2, pindel, varscan2
- COL15A1 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPZ | c.309_358del p.V104Hfs*17 (on ENST00000360986 / NM_001014447.3; = p.V93Hfs*17 on NM_003652.3) | Frame Shift Del (DEL) | VAF 60/238 reads (25%) | called by mutect2, pindel
- DDX27 | c.2258C>A p.T753N | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- DIAPH2 | c.2713A>T p.S905C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DMAP1 | c.1330del p.L444Sfs*18 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | called by mutect2, pindel
- DSEL | c.2572C>A p.H858N | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DST | c.20563C>T p.Q6855* (on ENST00000361203 / NM_001374722.1; = p.Q4552* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 27/127 reads (21%) | called by muse, mutect2, varscan2
- EID2B | c.196_244del p.G66Ifs*7 | Frame Shift Del (DEL) | VAF 52/268 reads (19%) | called by mutect2, pindel
- EIF2S3 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.316); called by muse, mutect2
- ELN | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 132/870 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ERBIN | c.3648del p.S1217Pfs*34 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | called by mutect2, pindel, varscan2
- EXTL3 | c.1621C>G p.P541A | Missense Mutation (SNP) | VAF 86/339 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FANCM | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 665/1261 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRB2 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 64/355 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- GPC6 | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 97/177 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GPRASP1 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GSK3A | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAPLN2 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.084); called by muse, mutect2
- HEATR5A | c.733A>T p.I245L | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPH1 | c.2056C>G p.Q686E | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.247); called by muse, mutect2
- ITIH4 | c.178A>G p.R60G | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- KCNQ3 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 77/682 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KEL | c.1074-1G>T p.X358_splice | Splice Site (SNP) | VAF 88/553 reads (16%) | called by muse, mutect2, varscan2
- MAP1B | c.3769C>T p.P1257S | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- MBD5 | c.1762C>G p.L588V | Missense Mutation (SNP) | VAF 52/267 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- MIB1 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 25/173 reads (14%) | called by muse, mutect2, varscan2
- MSX2 | c.350A>G p.Q117R | Missense Mutation (SNP) | VAF 70/350 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MUC12 | c.4483G>A p.E1495K (on ENST00000379442; = p.E1352K on NM_001164462.1) | Missense Mutation (SNP) | VAF 354/625 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.301); called by mutect2, varscan2
- MYO1F | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NPHP3 | c.3413dup p.L1138Ffs*3 | Frame Shift Ins (INS) | VAF 71/178 reads (40%) | called by mutect2, pindel, varscan2
- NPIPB11 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT tolerated, low confidence (0.5); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- OR13H1 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- OR1B1 | c.820C>G p.Q274E | Missense Mutation (SNP) | VAF 49/255 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PKHD1L1 | c.9481C>T p.H3161Y | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.326); called by muse, mutect2
- PLXNA3 | c.4537A>G p.T1513A | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKD1 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- PRTG | c.2965C>G p.Q989E | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAPGEF5 | c.296-1G>C p.X99_splice (on ENST00000401957 / NM_001367602.2; = p.X402_splice on NM_012294.5) | Splice Site (SNP) | VAF 46/209 reads (22%) | called by muse, mutect2, varscan2
- RIF1 | c.204C>G p.N68K | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- RIF1 | c.4307del p.N1436Ifs*23 | Frame Shift Del (DEL) | VAF 23/111 reads (21%) | called by mutect2, pindel, varscan2
- RYR1 | c.13582C>A p.P4528T | Missense Mutation (SNP) | VAF 60/319 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- SDK2 | c.554C>G p.A185G | Missense Mutation (SNP) | VAF 77/389 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SEC24C | c.435C>G p.I145M | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- SECISBP2L | c.2238C>G p.I746M (on ENST00000559471 / NM_001193489.2; = p.I701M on NM_014701.4) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SH3RF3 | c.2230C>T p.P744S | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SMG1 | c.10887G>T p.R3629S | Missense Mutation (SNP) | VAF 64/276 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SON | c.6752A>G p.N2251S | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- SPRY1 | c.860A>T p.Y287F | Missense Mutation (SNP) | VAF 41/281 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- SRMS | c.998A>T p.Q333L | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ST8SIA4 | c.661A>T p.S221C | Missense Mutation (SNP) | VAF 73/231 reads (32%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SYNE1 | c.19926C>G p.I6642M (on ENST00000367255 / NM_182961.4; = p.I6571M on NM_033071.3) | Missense Mutation (SNP) | VAF 63/318 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SYNE2 | c.13286A>C p.Q4429P | Missense Mutation (SNP) | VAF 90/1077 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2
- TEX15 | c.8183C>A p.P2728Q (on ENST00000256246; = p.P3111Q on NM_001350162.2) | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- TMEM232 | c.1772A>G p.E591G | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNFSF13B | c.477A>T p.Q159H | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, varscan2
- TNS1 | c.4412A>T p.E1471V | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- WDFY3 | c.7961G>A p.R2654K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.057); called by muse, mutect2
- WDR44 | c.2117A>G p.Y706C | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- ZC3H13 | c.398G>T p.R133I | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- ZEB2 | c.2923G>T p.G975C | Missense Mutation (SNP) | VAF 69/384 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZFYVE26 | c.4294C>G p.L1432V | Missense Mutation (SNP) | VAF 59/243 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF202 | c.1340A>C p.H447P | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- ZNF214 | c.36del p.F12Lfs*31 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | called by mutect2, pindel, varscan2
- ZNF560 | c.1949A>T p.H650L | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF667 | c.451A>G p.K151E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.307); called by muse, mutect2
- ABCA4 | c.2349G>A p.Q783= | Silent (SNP) | VAF 106/514 reads (21%) | called by muse, mutect2, varscan2
- ALDH1A1 | c.141G>A p.E47= | Silent (SNP) | VAF 24/201 reads (12%) | called by muse, mutect2, varscan2
- ALK | c.2598G>A p.S866= | Silent (SNP) | VAF 189/620 reads (30%) | catalogued as rs56304041, COSV101202870, COSV66560959; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANKFN1 | c.219G>A p.T73= | Silent (SNP) | VAF 41/205 reads (20%) | catalogued as rs370848906, COSV59447743; called by muse, mutect2, varscan2
- AP4M1 | c.90C>G p.A30= | Silent (SNP) | VAF 114/713 reads (16%) | catalogued as rs1418445713; called by muse, mutect2, varscan2
- ARHGAP26 | c.1606C>T p.L536= | Silent (SNP) | VAF 33/139 reads (24%) | catalogued as rs1436447934; called by muse, mutect2, varscan2
- ATXN7L1 | c.2499G>A p.L833= | Silent (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
- BRAP | c.1363C>T p.L455= | Silent (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- CARHSP1 | c.100C>T p.L34= | Silent (SNP) | VAF 35/160 reads (22%) | called by muse, mutect2, varscan2
- CCDC117 | c.651C>T p.L217= | Silent (SNP) | VAF 44/238 reads (18%) | called by muse, mutect2, varscan2
- CLCN1 | c.354G>C p.G118= | Silent (SNP) | VAF 104/700 reads (15%) | catalogued as COSV100578172; called by muse, mutect2, varscan2
- CNTNAP4 | c.603G>A p.L201= | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as rs966408033; called by muse, mutect2
- CREB3L1 | c.252G>A p.A84= | Silent (SNP) | VAF 106/415 reads (26%) | catalogued as rs111444829; called by muse, mutect2, varscan2
- CTCFL | c.1953C>T p.G651= | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as rs111292204, COSV54771084, COSV99712237; called by muse, mutect2, varscan2
- DSEL | c.2571G>A p.G857= | Silent (SNP) | VAF 25/156 reads (16%) | catalogued as rs1317140542, COSV59493564; called by muse, mutect2, varscan2
- DSG4 | c.1926A>T p.L642= | Silent (SNP) | VAF 82/287 reads (29%) | called by muse, mutect2, varscan2
- ELN | c.1437G>T p.V479= | Silent (SNP) | VAF 131/866 reads (15%) | called by muse, mutect2, varscan2
- FBN1 | c.1020G>A p.L340= | Silent (SNP) | VAF 74/434 reads (17%) | called by muse, varscan2
- FBXL19 | c.1989C>T p.R663= | Silent (SNP) | VAF 60/366 reads (16%) | called by muse, mutect2, varscan2
- FNDC1 | c.3240C>T p.D1080= | Silent (SNP) | VAF 60/172 reads (35%) | catalogued as COSV51932037; called by muse, mutect2, varscan2
- GATA3 | c.462G>A p.P154= | Silent (SNP) | VAF 30/181 reads (17%) | catalogued as rs1314875185, COSV60522957; called by muse, mutect2, varscan2
- GLI1 | c.262C>T p.L88= | Silent (SNP) | VAF 54/367 reads (15%) | catalogued as COSV57363281; called by muse, mutect2, varscan2
- GLIS1 | c.255C>T p.D85= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs753275055; called by muse, mutect2, varscan2
- KRT8 | c.186C>T p.G62= | Silent (SNP) | VAF 47/280 reads (17%) | called by muse, mutect2, varscan2
- LILRB3 | c.1926C>T p.I642= (on ENST00000346401; = p.I630= on NM_006864.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/222 reads (16%) | called by muse, mutect2, varscan2
- MAGEE1 | c.2452A>C p.R818= | Silent (SNP) | VAF 36/149 reads (24%) | called by muse, mutect2, varscan2
- MAP3K19 | c.291C>T p.S97= | Silent (SNP) | VAF 21/86 reads (24%) | called by muse, mutect2, varscan2
- MAPKAPK2 | c.39G>T p.P13= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs1447122596; called by muse, mutect2, varscan2
- MROH7 | c.2352C>T p.A784= | Silent (SNP) | VAF 43/199 reads (22%) | catalogued as COSV100274196; called by muse, mutect2, varscan2
- NACAD | c.4638G>A p.L1546= | Silent (SNP) | VAF 116/564 reads (21%) | called by muse, mutect2, varscan2
- NPAS2 | c.1926G>A p.P642= | Silent (SNP) | VAF 84/470 reads (18%) | catalogued as rs776277664, COSV100175648; called by muse, mutect2, varscan2
- NRXN1 | c.2263C>T p.L755= | Silent (SNP) | VAF 74/467 reads (16%) | catalogued as COSV100456458, COSV58490483; called by muse, mutect2, varscan2
- OR8D1 | c.582C>A p.L194= | Silent (SNP) | VAF 55/212 reads (26%) | called by muse, mutect2, varscan2
- PARN | c.1737G>A p.E579= | Silent (SNP) | VAF 114/272 reads (42%) | called by muse, mutect2, varscan2
- PCDHB8 | c.1221G>A p.E407= | Silent (SNP) | VAF 110/958 reads (11%) | catalogued as rs782067030; called by muse, mutect2, varscan2
- PMEL | c.1959C>T p.S653= | Silent (SNP) | VAF 34/171 reads (20%) | catalogued as rs1390391157; called by muse, mutect2
- PRPF8 | c.735C>G p.L245= | Silent (SNP) | VAF 172/502 reads (34%) | called by muse, mutect2, varscan2
- SDF2L1 | c.375C>T p.S125= | Silent (SNP) | VAF 154/535 reads (29%) | catalogued as rs1411810084; called by muse, mutect2, varscan2
- SEMA3D | c.1830T>C p.F610= | Silent (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- SERINC2 | c.1311C>G p.L437= (on ENST00000373709 / NM_178865.5; = p.L441= on NM_018565.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/362 reads (17%) | called by muse, mutect2, varscan2
- SLC28A1 | c.714C>T p.I238= | Silent (SNP) | VAF 71/434 reads (16%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.3276G>T p.P1092= | Silent (SNP) | VAF 28/147 reads (19%) | called by muse, mutect2, varscan2
- TMEM182 | c.30A>T p.G10= | Silent (SNP) | VAF 35/205 reads (17%) | catalogued as rs1357562708; called by muse, mutect2, varscan2
- ZFPM1 | c.2367C>A p.P789= | Silent (SNP) | VAF 63/183 reads (34%) | called by muse, mutect2, varscan2
- ZNF677 | c.597G>T p.L199= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV61721564; called by muse, mutect2, varscan2
- ZNF705A | c.411T>A p.T137= | Silent (SNP) | VAF 68/283 reads (24%) | called by muse, mutect2, varscan2
- ZSCAN20 | c.1299T>C p.S433= | Silent (SNP) | VAF 62/132 reads (47%) | called by muse, mutect2, varscan2
- CNTN4 | c.56-278A>G | Intron (SNP) | VAF 22/126 reads (17%) | catalogued as rs1267400814; called by muse, mutect2, varscan2
- CYTH2 | c.20-384T>G | Intron (SNP) | VAF 57/195 reads (29%) | called by muse, mutect2, varscan2
- DCHS2 | n.8196C>G | RNA (SNP) | VAF 46/137 reads (34%) | catalogued as rs768356361; called by muse, mutect2, varscan2
- FBRS | chr16:30664341 G>A | 5'Flank (SNP) | VAF 6/32 reads (19%) | catalogued as rs758283439; called by muse, mutect2, varscan2
- GSDMD | c.411-73G>A | Intron (SNP) | VAF 16/83 reads (19%) | catalogued as rs531981616; called by mutect2, varscan2
- IL36RN | c.*33G>A | 3'UTR (SNP) | VAF 107/465 reads (23%) | called by muse, mutect2, varscan2
- IPO5 | c.-4-38G>T | Intron (SNP) | VAF 194/402 reads (48%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-9603C>A | Intron (SNP) | VAF 103/491 reads (21%) | catalogued as rs144350483; called by muse, mutect2, varscan2
- NBPF25P | n.1219C>T | RNA (SNP) | VAF 294/600 reads (49%) | called by muse, mutect2, varscan2
- NFASC | c.-26G>T | 5'UTR (SNP) | VAF 54/326 reads (17%) | called by muse, mutect2, varscan2
- POLR2D | c.*7A>G | 3'UTR (SNP) | VAF 144/354 reads (41%) | catalogued as rs1393909476; called by muse, mutect2, varscan2
- SCN2B | c.*35C>T | 3'UTR (SNP) | VAF 97/399 reads (24%) | called by muse, mutect2, varscan2
- SDCCAG8 | c.-19C>T | 5'UTR (SNP) | VAF 81/385 reads (21%) | catalogued as rs773533104, COSV59418799; called by muse, mutect2, varscan2
- TRMT61A | c.*157C>T | 3'UTR (SNP) | VAF 32/151 reads (21%) | catalogued as rs1484033505; called by muse, mutect2, varscan2
- TTC19 | c.*785G>T | 3'UTR (SNP) | VAF 105/331 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.10361-5431C>G | Intron (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- VPS11 | chr11:119069331 G>A | 5'Flank (SNP) | VAF 47/178 reads (26%) | called by muse, mutect2, varscan2
- ZNF99 | c.*876T>A | 3'UTR (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
